Surgical pathology report (de-identified scan), TCGA case TCGA-H9-A6BY, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-H9-A6BY-01A (Primary Tumor).

[page 1 of 3]
Operative Procedure:
Prostatectomy, pelvic lymph node dissection

Pre-Operative Diagnosis:
Not provided

Post-Operative Diagnosis:
Not provided

Specimen Received:
A: Prostate and seminal vesicles
B: Right pelvic lymph nodes
C: Left pelvic lymph nodes

Final Pathologic Diagnosis:
A. Prostate and seminal vesicles, prostatectomy:

Histologic type: Prostatic adenocarcinoma
Variant histology present: No
Prostate size: 33 x 54 x 38 mm; weight: 42 g

Gleason score (primary + secondary): 3 + 4 = 7
Primary pattern (%): 3, 80 %
Secondary pattern (%): 4, 20 %
Tertiary pattern (%): Not applicable

Tumor quantitation:
Largest tumor focus: 32 mm (greatest dimension)
Additional dimensions: 27 x 15 mm
Location: Right posterior extending into anterior
Multifocality: Yes
Second largest focus: 21 mm (greatest dimension)
Location: Left posterior extending into right posterior

Extraprostatic extension: Yes
Focal or non-focal: Focal
Location(s): Right posterior
Seminal vesicle invasion: No
Cancer at surgical margin: No
Closest distance with location: <1 mm, left and right posterior
and right anterior
Incised specimen: No
Apex involvement: No
Bladder neck involvement: Yes, but not at the margin
Lymph-vascular invasion: No
Perineural invasion: Present

ICD-O-3

Adenocarcinoma, acinar
8140/3

Adenocarcinoma NOS
8140/3

Site Prostate NOS
C61.9

9/24/13

Primary Tumor Size Discrepancy		
Primary Tumor Discrepancy		

[page 2 of 3]
Treatment effect on carcinoma: No
Other histologic findings: High-grade prostatic intraepithelial
neoplasia
Lymph nodes submitted: Yes
0 positive / 19 submitted

Ancillary studies: None

Pathologic stage (2010) pT3a pN0 pM-not applicable

B. Lymph nodes (10), right pelvic, regional resection:
Ten lymph nodes with no pathologic change (0/10)

C. Lymph nodes (9), left pelvic, regional resection:
Nine lymph nodes with no pathologic change (0/9)

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

Received are three formalin filled containers all labeled with the patient's name

Part A is received additionally labeled "prostate and seminal vesicles." The specimen consists of a prostate gland with attached bilateral seminal vesicles and segments of vas deferens. The specimen is inked in the following manner: right side yellow, left side black, posterior aspect over-inked in red. The remaining gland has a weight of 42 g, and a length of 3.3 cm with additional dimensions of 5.4 x 3.8 cm. The apex and base prostatic margins of surgical resection are coned and submitted in cassettes A1-2, respectively. The remaining gland is step-sectioned in an apex to base manner with sections submitted as follows:

- A3-11 right posterior prostate gland apex to base manner;
- A12-20 left posterior prostate gland apex to base manner;
- A21 right anterior prostate gland level 2;
- A22 left anterior prostate gland level 3;
- A23 right anterior prostate gland level 4;
- A24 left anterior prostate gland level 6;
- A25 right anterior prostate gland level 6;
- A26 left anterior prostate gland level 7;
- A27 right anterior prostate gland level 8;
- A28-29 right and left prostate gland approaching interface with seminal vesicles, respectively;
- A30-32 right seminal vesicle and segment of vas in a base, mid to apex manner;
- A33-35 left seminal vesicle and vas in a base, mid to apex manner.

Part B is received additionally labeled "right pelvic nodes" and consists of

[page 3 of 3]
yellow, lobulated, fibrofatty tissues having aggregate dimensions of 5.5 x 3.5 cm by up to 1 cm. These tissues are placed in a "clearing agent" and a subsequent search reveals six probable lymph nodes that range from 0.5 to 3.5 cm in greatest dimension. The lymph node candidates are submitted as follows:

- B1 four whole probable lymph nodes;
- B2 one whole lymph node bisected;
- B3-4 one whole lymph node quadrisectioned, one-half in each cassette.

Part C is received additionally labeled "left pelvic nodes" and consists of yellow, lobulated, fibrofatty tissues having aggregate dimensions of 7 x 5.5 x 1 cm. These tissues are placed in a "clearing agent" and a subsequent search reveals six probable lymph nodes that range from 0.5 to 3 cm in greatest dimension. These lymph node candidates are submitted as follows:

- C1 two whole probable lymph nodes;
- C2 two whole probable lymph nodes;
- C3 one whole probable lymph node;
- C4-5 one whole lymph node bisected, one-half in each cassette.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Gender: M

Source: NCI Genomic Data Commons file 7dd4740a-354b-4e3d-91f3-50bfdd527f24 (TCGA-H9-A6BY.87EDA3C6-8BAC-49FD-8592-1D38812660E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).